Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-A8B0, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-A8B0-TTP1-C (Primary Tumor).

[page 1 of 2]
Material description

1. Lymph node N.10
2. Lymph node N.10
3. Lymph node N.8
4. Lymph node N.10
5. Lymph node N.11
6. Lower lobe, left lung
7. Lymph node N. 10 lingular artery
8. Bronchus at section level
9. Subaortic lymph node N.5

ICD-0-3

adeno carcinoma, with
mixed subtypes 8255/3

site: (L) lung, lower lobe c34.3

ICD-10

C34.32

Macro description

1. One anthracotic lymph node, major axis of 1,2 cm
2. One anthracotic lymph node, major axis of 0.7 cm
3. One anthracotic lymph node, major axis of 1.7 cm
4. Five anthracotic lymph nodes, the greatest with main axis of 1.3 cm
5. One anthracotic lymph node, major axis of 1 cm
6. 17 x 13 x 3 cm pulmonary lobe that, when you cut, shows greyish-blackish neoformation, hard compactness, regular margins, major axis of 2,5 cm. This neoformation is far from above pleura 0.4 cm. We close off a lymph node from hilum
7. One anthracotic lymph node, major axis of 2 cm
8. Irregular fragment of greyish tissue of 1,7 x 1 cm
9. Three anthracotic lymph nodes, greatest: main axis of 1.2 cm

hw
2/12/16

Micro description

1.2.3.4.5.6.7.8.9.

It is a poorly differentiated adenocarcinoma, mixed type, mainly solid, focally papillary. The neoplasm is made up of solid nests, sometimes centrally necrotic, and cords of cells of large size, with vesicular and round nucleus, prominent nucleolus, large, eosinophil or vacuolated, cytoplasm. Focally the proliferation shows papillary aspect. It is inserted fibrous desmoplastic stroma with inflammation. We observe vascular intrahematic intratumoral invasion.

Pleura free from neoplastic infiltration.

In the remaining parenchyma we observe chronic, not specific, bronchiolitis and slight bronchiolitis of respiratory type. Bronchial margin negative for neoplasm. Lymph nodes: all the lymph nodes examined are negative for metastases and show reactive, not specific, modifications.

[page 2 of 2]
Conclusion and Histopathological Diagnosis

1.2.3.4.5.7.9 Lymph nodes with reactive, not specific, modifications.

6. Poorly differentiated adenocarcinoma, mixed type (solid and papillary) 8. Bronchial margin negative for neoplasm

Staging pTNM: MISSING

Source: NCI Genomic Data Commons file 0c5a83ba-6e8d-4fcb-9fbf-f085652ee038 (CDDP-A8B0-TTP1.93EE08D5-9518-401E-9568-DE195CF6E1CA.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).